Somatic mutation profile of tumor specimen 0DNCOQ from CCDI case PBCBBM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 12.0 years (4,373 days).
Specimen 0DNCOQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d04787e-74cb-45aa-83a3-eb2d3fef1676.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNCGY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50b45ff0-2c4c-4d81-86d9-eb4c90a2a7ad

The open-access MAF lists 84 somatic variants for this specimen: 62 protein-altering or splice-affecting, 10 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 10, Intron 4, 5'UTR 4, 3'UTR 3, Nonsense Mutation 2, 5'Flank 1, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>G p.R465G (on ENST00000281708 / NM_001349798.2; = p.R385G on NM_018315.5) | Missense Mutation (SNP) | VAF 568/1048 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C1QTNF9 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 626/2062 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs780428044; called by muse, mutect2, varscan2
- CALB2 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 269/753 reads (36%) | catalogued as rs761608945; called by muse, mutect2, varscan2
- CHD3 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 850/1482 reads (57%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV57872921; called by muse, mutect2, varscan2
- CMYA5 | c.3095C>A p.A1032D | Missense Mutation (SNP) | VAF 501/1383 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV71411156; called by muse, mutect2, varscan2
- CNTNAP3B | c.2198C>G p.S733C | Missense Mutation (SNP) | VAF 66/470 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV59544543; called by muse, mutect2, varscan2
- ELMO2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 363/2032 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.59); catalogued as rs924016543, COSV51682599; called by muse, mutect2, varscan2
- GDPD1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 396/1463 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as rs749907330; called by muse, mutect2, varscan2
- KMT2C | c.14530G>A p.A4844T | Missense Mutation (SNP) | VAF 305/1041 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469176725, COSV51277101; called by muse, mutect2, varscan2
- NFASC | c.2690G>A p.R897H (on ENST00000339876 / NM_001378329.1; = p.R1000H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 595/2235 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs770267859, COSV58363886; called by muse, mutect2, varscan2
- NPIPB11 | c.671A>C p.H224P | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1247836458; called by muse, mutect2, varscan2
- NTSR1 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 415/1336 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as rs757431934; called by muse, mutect2, varscan2
- NXPE2 | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 226/1431 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV64941051; called by muse, mutect2, varscan2
- PCDHA6 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 311/925 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs782777129; called by muse, mutect2, varscan2
- PEG3 | c.3625C>T p.R1209W | Missense Mutation (SNP) | VAF 90/1646 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs780388034; called by muse, mutect2
- PPL | c.4916G>A p.R1639H | Missense Mutation (SNP) | VAF 338/683 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759206400, COSV99277648; called by muse, mutect2, varscan2
- R3HDML | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 322/1082 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs146968536; called by muse, mutect2, varscan2
- SLITRK2 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 114/1398 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1218861987, COSV59427869; called by muse, mutect2
- SMARCA2 | c.3797G>A p.R1266Q | Missense Mutation (SNP) | VAF 152/898 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV61804759; called by muse, mutect2, varscan2
- SQLE | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 366/2736 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104380855; called by muse, mutect2, varscan2
- SUN2 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 286/804 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs549404842, COSV53283482; called by muse, mutect2, varscan2
- TAF1 | c.3482G>T p.R1161L (on ENST00000373790 / NM_138923.4; = p.R1182L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 884/1077 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52111361, COSV99335726; called by muse, mutect2, varscan2
- TMEM79 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 1166/1699 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs752608151, COSV104403515; called by muse, mutect2, varscan2
- TNXB | c.7189G>A p.V2397M (on ENST00000647633; = p.V2150M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 457/1369 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs373436925; called by muse, mutect2, varscan2
- TPCN1 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 269/981 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59234264; called by muse, mutect2, varscan2
- VEGFA | c.667C>T p.R223C (on ENST00000523873 / NM_001171623.1; = p.R386C on NM_003376.6) | Missense Mutation (SNP) | VAF 754/1387 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752907384; called by muse, mutect2, varscan2
- VRTN | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 245/735 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1027923829; called by muse, mutect2, varscan2
- ABCA13 | c.4369A>C p.N1457H | Missense Mutation (SNP) | VAF 435/1508 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ALPK3 | c.4933G>T p.A1645S | Missense Mutation (SNP) | VAF 348/667 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMER2 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 198/881 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAM | c.532A>G p.N178D | Missense Mutation (SNP) | VAF 198/1341 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- CAMSAP3 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 115/534 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- CAMSAP3 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 119/533 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CATIP | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 60/1556 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.258); called by muse, mutect2
- CHSY1 | c.2057G>T p.G686V | Missense Mutation (SNP) | VAF 649/1759 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP3B | c.1820T>C p.I607T | Missense Mutation (SNP) | VAF 175/1184 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- COL4A6 | c.3208G>T p.D1070Y | Missense Mutation (SNP) | VAF 599/683 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CREBBP | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 476/958 reads (50%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- DAB1 | c.594C>G p.Y198* | Nonsense Mutation (SNP) | VAF 360/760 reads (47%) | called by muse, mutect2, varscan2
- DIS3 | c.638G>C p.C213S | Missense Mutation (SNP) | VAF 62/1700 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.6587C>T p.P2196L | Missense Mutation (SNP) | VAF 381/1228 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- DOCK7 | c.5740A>G p.T1914A (on ENST00000635253 / NM_001367561.1; = p.T1883A on NM_033407.3) | Missense Mutation (SNP) | VAF 300/845 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DTX1 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 256/892 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GABBR2 | c.1893+3A>C | Splice Region (SNP) | VAF 56/610 reads (9%) | called by muse, mutect2
- HNF1A | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 303/1190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXC8 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 384/1345 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- IL17RC | c.1735G>T p.A579S (on ENST00000295981 / NM_153461.4; = p.A493S on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 636/1053 reads (60%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- KDM5C | c.3392_3393del p.E1131Afs*72 | Frame Shift Del (DEL) | VAF 518/910 reads (57%) | called by pindel, varscan2
- LMO7 | c.2602C>G p.R868G (on ENST00000357063; = p.R549G on NM_005358.5) | Missense Mutation (SNP) | VAF 599/1542 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYOCD | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 470/1478 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NAT10 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 112/703 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NF1 | c.5040dup p.N1681* (on ENST00000358273 / NM_001042492.3; = p.N1660* on NM_000267.3) | Frame Shift Ins (INS) | VAF 718/1125 reads (64%) | called by mutect2, pindel, varscan2
- OPALIN | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 90/1300 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.654); called by muse, mutect2
- PDE2A | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 388/1007 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PEX26 | c.281C>A p.A94E | Missense Mutation (SNP) | VAF 468/987 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAF1 | c.1425T>A p.F475L | Missense Mutation (SNP) | VAF 499/867 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ROBO4 | c.2720C>A p.A907D | Missense Mutation (SNP) | VAF 395/1315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC16A14 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 661/1244 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SLCO1B3 | c.171G>T p.R57S | Missense Mutation (SNP) | VAF 316/1326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STXBP2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 291/1311 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SYNE1 | c.25798C>G p.H8600D (on ENST00000367255 / NM_182961.4; = p.H8552D on NM_033071.3) | Missense Mutation (SNP) | VAF 65/1442 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- UNC5D | c.1465T>C p.F489L | Missense Mutation (SNP) | VAF 427/2718 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMTR1 | c.1029T>C p.S343= | Silent (SNP) | VAF 550/1691 reads (33%) | called by muse, mutect2, varscan2
- DLGAP3 | c.249G>T p.G83= | Silent (SNP) | VAF 312/848 reads (37%) | catalogued as rs753115472; called by mutect2, varscan2
- FCER1G | c.102G>T p.L34= | Silent (SNP) | VAF 482/2012 reads (24%) | catalogued as rs538083329; called by muse, mutect2, varscan2
- GMEB2 | c.1347G>A p.P449= | Silent (SNP) | VAF 361/1744 reads (21%) | catalogued as rs538984558; called by muse, mutect2, varscan2
- KRTAP19-2 | c.150C>A p.G50= | Silent (SNP) | VAF 323/1504 reads (21%) | called by muse, mutect2, varscan2
- LBX1 | c.699C>T p.G233= | Silent (SNP) | VAF 275/551 reads (50%) | called by muse, mutect2, varscan2
- POTEM | c.1317T>A p.A439= | Silent (SNP) | VAF 100/537 reads (19%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1599C>A p.V533= | Silent (SNP) | VAF 577/1378 reads (42%) | called by muse, mutect2, varscan2
- TIAM1 | c.4641G>A p.A1547= | Silent (SNP) | VAF 306/981 reads (31%) | catalogued as rs762321271, COSV54545352; called by muse, mutect2, varscan2
- TPO | c.2565T>G p.A855= | Silent (SNP) | VAF 293/1149 reads (26%) | called by muse, mutect2, varscan2
- C16orf89 | c.*13G>A | 3'UTR (SNP) | VAF 157/292 reads (54%) | catalogued as rs1424424535, COSV100280765; called by muse, mutect2, varscan2
- CHN2 | c.654+3505C>T | Intron (SNP) | VAF 81/290 reads (28%) | called by muse, mutect2, varscan2
- INTS7 | c.510-86C>T | Intron (SNP) | VAF 469/676 reads (69%) | catalogued as rs1012318422; called by muse, mutect2, varscan2
- NDUFS3 | c.*12G>A | 3'UTR (SNP) | VAF 311/967 reads (32%) | catalogued as rs763583155, COSV55454407; called by muse, mutect2, varscan2
- NEFM | chr8:24913760 C>T | 5'Flank (SNP) | VAF 231/1894 reads (12%) | called by muse, mutect2, varscan2
- NPDC1 | c.-69C>G | 5'UTR (SNP) | VAF 149/349 reads (43%) | called by muse, mutect2, varscan2
- PHF14 | c.1456-25_1456-24del | Intron (DEL) | VAF 172/666 reads (26%) | called by mutect2, pindel, varscan2
- PPP2R2A | c.*82G>C | 3'UTR (SNP) | VAF 83/629 reads (13%) | called by muse, mutect2, varscan2
- PTK2 | c.2710-1237A>G | Intron (SNP) | VAF 385/1382 reads (28%) | called by muse, mutect2, varscan2
- TMOD1 | c.-33G>T | 5'UTR (SNP) | VAF 298/712 reads (42%) | catalogued as COSV99403776; called by muse, mutect2, varscan2
- URAD | c.-30C>A | 5'UTR (SNP) | VAF 56/472 reads (12%) | catalogued as rs770879827; called by muse, mutect2, varscan2
- VSTM1 | c.-19T>A | 5'UTR (SNP) | VAF 26/844 reads (3%) | called by muse, mutect2
